Surgical pathology report (de-identified scan), TCGA case TCGA-YF-AA3L, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Puerto Rico, specimen TCGA-YF-AA3L-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Spec #:

Taken:

Received:

Reported:

SPECIMEN

- A. Ureter
- B. Ureter
- C. BLADDER
- D. Appendix
- E. Lymph Node
- F. Lymph Node
- G. Lymph Node

ICD-O 3
Carcinoma, urothelial NOS 5120/3
Site: ^{C67.2} Bladder, lateral wall C67.2
^{Path} Bladder NOS C67.9
J2 0/20/14

CLINICAL INFORMATION

Clinical History: Bladder CA who presented with hematuria
Pre-Operative Clinical Diagnosis: Bladder cancer
Post-Operative Clinical Diagnosis: Bladder cancer

INTRAOPERATIVE CONSULTATION DX

- A. Ureter, right, margin biopsy:
- Negative for malignancy

- B. Ureter, left, margin biopsy:
- Negative for malignancy

Pathologist:

FINAL PATHOLOGIC DIAGNOSIS

- A. Ureter, right, margin biopsy:
- Negative for malignancy

- B. Ureter, left, margin, biopsy:
- Negative for malignancy

- C. Bladder, uterus, ovary, fallopian tube, radical cystohysterectomy, bilateral salpingo-oophorectomy:
- Infiltrating urothelial carcinoma, high grade
- The tumor measures 5 cm in greatest dimension
- The tumor invades muscularis propria (detrusor muscle)
- Margins are free of tumor
- Positive for lymphovascular invasion
- Other findings:
- Chronic cervicitis
- Proliferative endometrium, partially autolyzed
- Leiomyoma

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

- Fallopian tubes: Unremarkable
- Ovaries with corpora albicantia

pT2bNo Stage II

D. Vermiform appendix, appendectomy:

- Vermiform appendix, unremarkable
- Negative for malignancy

E. Lymph node, pelvic, right, resection:

- Two lymph nodes negative for metastasis

F. Lymph node, pelvic, left, resection:

- Six lymph nodes negative for metastasis

G. Labeled as "Urethra, bladder" partial resection:

- Fragment of fibroconnective tissue with squamous epithelium and embryonic remnants.

GROSS DESCRIPTION

A. Received fresh, labeled "bladder and right ureter (suture distal side attached to the bladder)" is a segment of ureter that measures 0.4 x 0.3 cm. The entire specimen is frozen for intraoperative consultation in one tissue block. (ST1)

B. Received fresh, labeled "bladder and left ureter (suture distal side attached to the bladder)" is a segment of ureter that measures 0.4 cm in length by 0.4 cm. The entire specimen is frozen for intraoperative consultation in one tissue block. (ST1)

C. Received in formalin, labeled "bladder" is a radical cystohysterectomy specimen containing bladder (11 x 6 x 6 cm), uterus (10 x 6 x 4 cm), and right ureter (7 cm in length by 0.5 cm in diameter) and left ureter (8 cm in length by 0.5 cm in diameter). There is a soft, tan-pink papillary tumor (5 x 4.5 x 2.5 cm) located at the right lateral and posterior wall. The tumor extends 1 cm from the deep margin. The remainder of the bladder mucosa is edematous and congested. The right and left ureters are unremarkable. There is an ulcerated hemorrhagic mucosae in the left lateral wall of the bladder that measures 3 x 2 cm. The uterus has both adnexa attached. The uterus weighs 200 g and measures 10 x 6.3 x 6 cm of which the lower 4 x 4 x 3.5 cm corresponds to the cervix. The serosa is pale-brown and smooth without fibrous adhesions. The external os is slit-like measuring 1.5 cm in length. The squamocolumnar junction is easily identified. The exocervix is covered by smooth glistening white mucosa. The endocervical canal is longitudinally trabeculated. The endometrial cavity is triangular measuring 2 cm cornu to cornu by 4 cm in length. The endometrium is pink-tan measuring up to 0.3 cm in thickness. The myometrium at the level of the fundus measures 1.5 cm. The myometrium presents a subserosal myoma that measures 1.5 cm in greatest diameter that has a white tan whorled appearance without hemorrhage or necrosis.

The right fallopian tube (7 x 0.7 cm) is fimbriated and unremarkable. The left fallopian tube (5 x 1 cm in diameter) is unremarkable. The right ovary (2 x 1 x 0.5 cm) and left ovary (3 x 1.5 x 1 cm) are cerebiform and presents cysts measuring from 0.3 to 0.5 cm.

1-3: deepest invasion, 4-6: representative section of tumor, 7: right lateral wall, 8: left lateral wall, 9: posterior wall, 10-12: fatty tissue, 13: anterior cervix, 14: posterior cervix, 15: anterior endometrium and myometrium, 16: posterior endometrium and myometrium, 17: myoma, 18: right ovary and fallopian tube, 19: left ovary and fallopian tube

D. Received in formalin, labeled "vermiform appendix and appendix" is a vermiform appendix measuring 6 cm in length by 0.7 cm in diameter. The serosal surface is smooth and glistening. On section, the wall is tan and measures 0.2 cm in thickness. The mucosa is tan and appears intact. (RS1)

E. Received in formalin, labeled "broadipose tissue and right pelvic nodule" is an irregular fragment of broadipose tissue that measures 3.5 x 1 x 0.5 cm. There are two lymph nodes that measures from 0.5 x 1 cm. (RS1)

F. Received in formalin, labeled "broadipose tissue and left pelvic nodule" are three irregular fragments of broadipose tissue that measure in aggregate 2.5 x 2 x 0.7 cm. There are six lymph nodes that measures from 0.5 to 1 cm.

G. Received in formalin, labeled "bladder and left nodule, urethra with bladder" is a portion of bladder and urethra that measures 7 x 4 x 2 cm. The mucosa is edematous. No lesions identified. (RS1)

Dictated by:

Source: NCI Genomic Data Commons file 2c5020ac-7a6a-4e0e-ade5-63db581a7279 (TCGA-YF-AA3L.B30B0CE0-2C49-4970-A67A-1F777A4E00BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).